FM case AD389 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas.
https://portal.gdc.cancer.gov/cases/ac9e37d2-2ca5-4403-ae21-a1093f23fc04

Male, 63.3 years: Adenocarcinoma, NOS (ICD-O-3 8140/3). Tumor nuclei on the sequenced sample's slide: 70% (pathologist estimate recorded by GDC). Sample type: Tumor.
